Somatic mutation profile of tumor specimen TCGA-22-4601-01A (aliquot TCGA-22-4601-01A-01D-1441-08) from TCGA case TCGA-22-4601, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 73.7 years (26,937 days).
Specimen TCGA-22-4601-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f950fb71-70f1-4507-a815-21d020a67d83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-4601-11A (Solid Tissue Normal), aliquot TCGA-22-4601-11A-01D-1441-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0a2fec9-61f2-4251-a7e0-377ccf52e7ed

The open-access MAF lists 192 somatic variants for this specimen: 141 protein-altering or splice-affecting, 48 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 118, Silent 48, Frame Shift Del 9, Nonsense Mutation 7, Splice Site 4, Intron 2, Translation Start Site 1, Splice Region 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 47/63 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACKR1 | c.366C>A p.S122R | Missense Mutation (SNP) | VAF 60/151 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.134); catalogued as rs563566546, COSV63672468; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3952G>T p.V1318F | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV65877507; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4048C>A p.L1350M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.837); catalogued as COSV65877510; called by muse, mutect2
- ADGRG4 | c.7981C>T p.Q2661* | Nonsense Mutation (SNP) | VAF 57/178 reads (32%) | catalogued as COSV54953373; called by muse, mutect2, varscan2
- ANK3 | c.2441C>T p.T814I | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as rs374740918; called by muse, mutect2, varscan2
- ANKRD34A | c.405G>C p.K135N | Missense Mutation (SNP) | VAF 60/99 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as COSV60160721; called by muse, mutect2, varscan2
- ARMC2 | c.907G>A p.G303R | Missense Mutation (SNP) | VAF 121/182 reads (66%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.578); catalogued as COSV64550702; called by muse, mutect2, varscan2
- ATP8B4 | c.1818G>T p.K606N | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.102); catalogued as COSV52713047; called by muse, mutect2, varscan2
- C2CD3 | c.1689C>G p.S563R | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as COSV58091964; called by muse, mutect2, varscan2
- CARS1 | c.8A>G p.D3G | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV53452860; called by mutect2, varscan2
- CCDC122 | c.366G>T p.M122I | Missense Mutation (SNP) | VAF 82/116 reads (71%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV55709062; called by muse, mutect2, varscan2
- CCDC57 | c.2725C>G p.R909G | Missense Mutation (SNP) | VAF 96/274 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV100148548, COSV60752741; called by muse, mutect2
- CCNQ | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 75/276 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.63); catalogued as rs781921854, COSV99367881; called by muse, mutect2, varscan2
- CDC25B | c.266C>A p.S89Y (on ENST00000245960 / NM_021873.3; = p.S75Y on NM_004358.4) | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.502); catalogued as COSV55655626; called by muse, mutect2, varscan2
- CDK1 | c.880A>G p.I294V | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.558); catalogued as COSV57349350; called by muse, mutect2
- CHD7 | c.2138A>C p.K713T | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as COSV71108899; called by muse, mutect2, varscan2
- COL22A1 | c.3448-2A>C p.X1150_splice | Splice Site (SNP) | VAF 3/13 reads (23%) | catalogued as COSV100276518; called by muse, varscan2
- COL4A6 | c.4769G>T p.C1590F | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57863306; called by muse, mutect2, varscan2
- COP1 | c.2104G>C p.A702P | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58165427; called by muse, mutect2
- CTNNA2 | c.1214C>A p.A405D | Missense Mutation (SNP) | VAF 63/95 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58145218; called by muse, mutect2, varscan2
- CUBN | c.1923T>A p.D641E | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0.015); catalogued as COSV64712858; called by muse, mutect2, varscan2
- DSCAML1 | c.3615C>G p.I1205M (on ENST00000321322; = p.I1145M on NM_020693.4) | Missense Mutation (SNP) | VAF 53/211 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); catalogued as COSV58387530; called by muse, mutect2, varscan2
- EEF1G | c.615del p.E206Kfs*2 | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | catalogued as COSV61321806; called by mutect2, pindel, varscan2
- EFHB | c.888C>A p.N296K | Missense Mutation (SNP) | VAF 67/117 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.314); catalogued as COSV55546803; called by muse, mutect2, varscan2
- EGFR | c.3056C>T p.P1019L | Missense Mutation (SNP) | VAF 75/122 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51789475; called by muse, mutect2, varscan2
- EPHA3 | c.1114C>T p.Q372* | Nonsense Mutation (SNP) | VAF 61/86 reads (71%) | catalogued as COSV60700706; called by muse, mutect2, varscan2
- EYA2 | c.1128G>T p.W376C | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57941187; called by muse, mutect2, varscan2
- F9 | c.478G>A p.G160R | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM030846, CM952071, COSV54379627; called by muse, mutect2, varscan2
- FAM104B | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV59776202; called by muse, mutect2, varscan2
- FAT4 | c.13405G>T p.A4469S | Missense Mutation (SNP) | VAF 75/175 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100627322, COSV58700481; called by muse, mutect2, varscan2
- FBXO4 | c.1160G>A p.R387K | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV55851738; called by muse, mutect2
- FOXM1 | c.1364C>T p.P455L | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV61205712; called by muse, varscan2
- FZD2 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV59528505; called by muse, mutect2, varscan2
- GABRB2 | c.1309T>C p.S437P (on ENST00000274547; = p.S399P on NM_000813.3) | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.529); catalogued as COSV50906775; called by muse, mutect2
- GALNT16 | c.232C>G p.Q78E | Missense Mutation (SNP) | VAF 53/84 reads (63%) | SIFT tolerated (0.69); PolyPhen benign (0.01); catalogued as COSV61885453; called by muse, mutect2, varscan2
- GAS7 | c.190G>A p.G64R (on ENST00000432992 / NM_201433.2; = p.G4R on NM_201432.2) | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.022); catalogued as rs1228455463, COSV60434282; called by muse, mutect2, varscan2
- GBA | c.1209C>G p.S403R | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59169434, COSV59170272; called by muse, mutect2, varscan2
- GPATCH8 | c.1003G>T p.D335Y | Missense Mutation (SNP) | VAF 105/268 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as rs778450026, COSV59194098; called by muse, mutect2, varscan2
- GPC3 | c.418C>A p.Q140K | Missense Mutation (SNP) | VAF 93/270 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV63662075; called by muse, mutect2, varscan2
- GRIA4 | c.647A>C p.E216A | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as COSV56889849; called by muse, mutect2, varscan2
- GRIK2 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 79/139 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59726984; called by muse, mutect2, varscan2
- GRIPAP1 | c.1925G>A p.R642H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs782625013, COSV64551644; called by muse, mutect2, varscan2
- HEPH | c.1655G>A p.G552D (on ENST00000343002; = p.G285D on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100294436, COSV57961600; called by muse, mutect2, varscan2
- HYAL1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 35/42 reads (83%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs782350623, COSV56497236; called by muse, mutect2, varscan2
- IRX2 | c.797A>T p.D266V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV57410568; called by muse, mutect2, varscan2
- KCNG4 | c.92T>C p.M31T | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV57583374; called by muse, mutect2, varscan2
- KDM4D | c.1181G>A p.G394E | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV58634234; called by muse, mutect2, varscan2
- KLHL15 | c.1704C>A p.N568K | Missense Mutation (SNP) | VAF 104/236 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV60139860; called by muse, mutect2, varscan2
- KLK6 | c.40+1G>T p.X14_splice | Splice Site (SNP) | VAF 46/147 reads (31%) | catalogued as COSV59565356; called by muse, mutect2, varscan2
- KRT76 | c.583G>T p.A195S | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1355656071, COSV60119831; called by muse, mutect2, varscan2
- LRFN5 | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 46/73 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.79); catalogued as COSV53250952; called by muse, mutect2, varscan2
- LRP2 | c.8500A>G p.I2834V | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs374622140; called by muse, mutect2, varscan2
- LRRC7 | c.4708C>G p.Q1570E (on ENST00000651989 / NM_001370785.2; = p.Q1490E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.978); catalogued as COSV50437777; called by muse, mutect2, varscan2
- LSS | c.1406A>T p.E469V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV62700113, COSV62700566; called by muse, mutect2, varscan2
- LTBP3 | c.301G>T p.D101Y | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57239763; called by muse, mutect2, varscan2
- MAGI3 | c.1466C>T p.T489I | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.719); catalogued as COSV56832986; called by muse, mutect2
- MINDY1 | c.1244T>A p.L415Q | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56498351; called by muse, mutect2, varscan2
- MON2 | c.4267A>G p.K1423E | Missense Mutation (SNP) | VAF 88/209 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0.117); catalogued as COSV54805597; called by muse, mutect2, varscan2
- MYH2 | c.1535C>A p.T512K | Missense Mutation (SNP) | VAF 104/306 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV55435392; called by muse, mutect2, varscan2
- MYO18A | c.1649A>G p.N550S | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.157); catalogued as COSV62865005; called by muse, mutect2
- MYO1F | c.1700C>A p.A567D | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57793589; called by muse, mutect2, varscan2
- NAALADL1 | c.267C>A p.D89E | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV60523449; called by muse, mutect2, varscan2
- NACA2 | c.440G>C p.G147A | Missense Mutation (SNP) | VAF 152/391 reads (39%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.992); catalogued as COSV71713116; called by muse, mutect2, varscan2
- NHS | c.944A>G p.Q315R | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66273495; called by muse, mutect2, varscan2
- NR1I3 | c.649T>C p.F217L | Missense Mutation (SNP) | VAF 82/234 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV63467593; called by muse, mutect2, varscan2
- NRK | c.1484C>G p.S495C | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.085); catalogued as COSV54593285; called by muse, mutect2, varscan2
- NRN1 | c.200+1G>C p.X67_splice | Splice Site (SNP) | VAF 70/258 reads (27%) | catalogued as COSV55205320, COSV55205413; called by muse, mutect2, varscan2
- NTRK1 | c.1603G>T p.E535* | Nonsense Mutation (SNP) | VAF 45/117 reads (38%) | catalogued as COSV62324809; called by muse, mutect2, varscan2
- OLFM2 | c.460A>T p.R154W | Missense Mutation (SNP) | VAF 53/74 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV53429567; called by muse, mutect2, varscan2
- OLFML1 | c.199A>G p.I67V | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV61402465; called by muse, mutect2, varscan2
- OR2A25 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.275); catalogued as COSV68717063; called by muse, mutect2, varscan2
- OR2A25 | c.523C>T p.H175Y | Missense Mutation (SNP) | VAF 78/272 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68717065; called by muse, varscan2
- OR2J3 | c.930G>T p.W310C | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV65848887; called by muse, mutect2, varscan2
- OR51M1 | c.853C>G p.H285D | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV60784234, COSV60784280, COSV60785593; called by muse, mutect2, varscan2
- OR52B6 | c.613C>A p.H205N | Missense Mutation (SNP) | VAF 84/294 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV61447660; called by muse, mutect2, varscan2
- OR52N1 | c.228C>A p.C76* | Nonsense Mutation (SNP) | VAF 41/116 reads (35%) | catalogued as COSV57693171; called by muse, mutect2, varscan2
- OR5B2 | c.793T>A p.S265T | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.344); catalogued as COSV100222918, COSV56907956; called by muse, mutect2, varscan2
- OR5L1 | c.320G>A p.C107Y | Missense Mutation (SNP) | VAF 68/218 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV61733421; called by muse, mutect2, varscan2
- OR5P2 | c.922C>T p.H308Y | Missense Mutation (SNP) | VAF 96/216 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV61490290; called by muse, mutect2, varscan2
- OR8G1 | c.672C>A p.S224R | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.182); catalogued as COSV100422240, COSV100422245; called by muse, mutect2, varscan2
- PARVG | c.337G>A p.V113M | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.853); catalogued as rs375768996, COSV63561657; called by muse, mutect2, varscan2
- PAX1 | c.973G>A p.G325S | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs200890498, COSV68271527; called by muse, mutect2, varscan2
- PCDHB10 | c.567G>A p.M189I | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV53377435; called by muse, mutect2
- PDP2 | c.371G>C p.R124P | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV61240368, COSV61241203; called by muse, mutect2, varscan2
- PLP2 | c.325C>A p.H109N | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV66239545; called by muse, mutect2, varscan2
- PNLIPRP3 | c.599C>A p.T200N | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV65047599; called by muse, mutect2, varscan2
- RB1 | c.684del p.K228Nfs*36 | Frame Shift Del (DEL) | VAF 42/87 reads (48%) | catalogued as CM030497; called by mutect2, pindel, varscan2
- RBL1 | c.1316G>A p.C439Y | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.542); catalogued as rs908481549, COSV60329325; called by muse, mutect2, varscan2
- RELN | c.10055C>T p.P3352L | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV58995270, COSV59024722; called by muse, mutect2, varscan2
- RFC4 | c.578G>T p.R193I | Missense Mutation (SNP) | VAF 76/252 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56216514; called by muse, mutect2, varscan2
- RHOBTB3 | c.611G>A p.S204N | Missense Mutation (SNP) | VAF 64/93 reads (69%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.747); catalogued as COSV66101750; called by muse, mutect2, varscan2
- RIMS4 | c.305C>A p.P102Q | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV65719512; called by muse, mutect2, varscan2
- RPGRIP1L | c.3883A>G p.T1295A | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV50904352; called by muse, mutect2, varscan2
- RSAD2 | c.532A>G p.I178V | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT tolerated (0.59); PolyPhen benign (0.127); catalogued as COSV65908197; called by muse, mutect2, varscan2
- SH3RF2 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63038344; called by muse, mutect2
- SLC7A3 | c.1808G>C p.R603T | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV53227059; called by muse, mutect2, varscan2
- SLCO1A2 | c.448A>G p.T150A | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV56599972; called by muse, mutect2, varscan2
- SLCO1C1 | c.1023T>C p.D341= | Splice Region (SNP) | VAF 46/140 reads (33%) | catalogued as COSV56870210, COSV56870955; called by muse, mutect2, varscan2
- SLFN11 | c.2471A>T p.Y824F | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.099); catalogued as COSV57698278; called by muse, mutect2, varscan2
- SLITRK4 | c.1988C>A p.S663Y | Missense Mutation (SNP) | VAF 82/291 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV62023124; called by muse, mutect2, varscan2
- SNRNP200 | c.2077A>C p.T693P | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV60488923; called by muse, mutect2, varscan2
- SP140 | c.489A>C p.Q163H | Missense Mutation (SNP) | VAF 38/56 reads (68%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.913); catalogued as COSV59448380; called by muse, mutect2, varscan2
- SPICE1 | c.2251C>T p.Q751* | Nonsense Mutation (SNP) | VAF 275/373 reads (74%) | catalogued as COSV55619687; called by muse, mutect2, varscan2
- SSH2 | c.3706A>G p.K1236E | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV52169948; called by muse, mutect2, varscan2
- STAC | c.1070G>T p.G357V | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56208933; called by muse, mutect2, varscan2
- STK11IP | c.1675C>G p.L559V | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55247395, COSV55257568; called by muse, mutect2, varscan2
- SUSD2 | c.762C>A p.S254R | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV64203377; called by muse, mutect2, varscan2
- SYNJ1 | c.2989G>C p.E997Q | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.249); catalogued as COSV59146680; called by muse, mutect2, varscan2
- SYT17 | c.1163A>G p.Y388C | Missense Mutation (SNP) | VAF 78/185 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62545762; called by muse, mutect2, varscan2
- TCHP | c.452G>T p.R151L | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57165262; called by muse, mutect2, varscan2
- TENM1 | c.1211T>A p.I404N | Missense Mutation (SNP) | VAF 72/246 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV64429322; called by muse, mutect2, varscan2
- TENM3 | c.4765A>G p.I1589V | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as rs376065308; called by muse, mutect2, varscan2
- TFE3 | c.1003+1G>T p.X335_splice | Splice Site (SNP) | VAF 17/60 reads (28%) | catalogued as COSV59946487; called by muse, mutect2, varscan2
- TFE3 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as COSV100252368, COSV59946503; called by muse, mutect2, varscan2
- TGIF2LX | c.292T>A p.S98T | Missense Mutation (SNP) | VAF 129/362 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.306); catalogued as COSV52213758; called by muse, varscan2
- TLE3 | c.914G>C p.G305A | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV58168229; called by muse, mutect2
- TRO | c.3841G>T p.G1281C | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV51499999; called by muse, mutect2, varscan2
- TUBAL3 | c.829A>G p.T277A | Missense Mutation (SNP) | VAF 99/228 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.022); catalogued as COSV66814132; called by muse, mutect2, varscan2
- UBE2U | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV64280751; called by muse, mutect2, varscan2
- UGT3A1 | c.1291A>G p.K431E | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.101); catalogued as COSV57097170; called by muse, mutect2, varscan2
- UGT3A1 | c.328C>T p.L110F | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV57097180, COSV57097765; called by muse, mutect2, varscan2
- VWF | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV54616485; called by muse, mutect2, varscan2
- WAS | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV61920215; called by muse, mutect2, varscan2
- XIRP2 | c.4555C>T p.L1519F (on ENST00000628543; = p.L1694F on NM_152381.6) | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs767948555, COSV54692715, COSV99746876; called by muse, mutect2, varscan2
- ZDHHC15 | c.62C>A p.S21Y | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV64901237; called by muse, mutect2, varscan2
- ZNF200 | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 75/188 reads (40%) | catalogued as rs761950506, COSV67723629; called by muse, mutect2, varscan2
- ZNF292 | c.5362C>G p.Q1788E | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as rs1230532490, COSV60537663; called by muse, mutect2
- ZNF490 | c.1547C>T p.S516F | Missense Mutation (SNP) | VAF 136/200 reads (68%) | SIFT tolerated (0.12); PolyPhen benign (0.394); catalogued as COSV61007652; called by muse, mutect2, varscan2
- ZNF528 | c.1636G>T p.E546* | Nonsense Mutation (SNP) | VAF 35/97 reads (36%) | catalogued as COSV64618996; called by muse, mutect2, varscan2
- ZNF761 | c.1801A>G p.T601A | Missense Mutation (SNP) | VAF 80/177 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV100483530, COSV61888015; called by muse, mutect2, varscan2
- ADGRL2 | c.3603_3622del p.A1202Rfs*21 | Frame Shift Del (DEL) | VAF 13/92 reads (14%) | called by mutect2, pindel
- AIRE | c.423del p.A142Rfs*5 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | called by pindel, varscan2
- AL121899.2 | c.529del p.E177Kfs*16 | Frame Shift Del (DEL) | VAF 61/147 reads (41%) | called by mutect2, pindel, varscan2
- CNR1 | c.871_880del p.V291Tfs*15 | Frame Shift Del (DEL) | VAF 28/79 reads (35%) | called by mutect2, pindel, varscan2
- HGF | c.1430del p.I477Kfs*4 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | called by mutect2, pindel, varscan2
- KRTAP6-2 | c.19_27del p.G7_Y9del | In Frame Del (DEL) | VAF 16/86 reads (19%) | called by pindel, varscan2
- MAGEB6B | c.460A>T p.T154S | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- OR11H1 | c.520G>T p.G174C | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); called by mutect2, varscan2
- SDR39U1 | c.475del p.V159Lfs*44 | Frame Shift Del (DEL) | VAF 5/10 reads (50%) | called by mutect2, varscan2
- VRTN | c.983del p.G328Afs*47 | Frame Shift Del (DEL) | VAF 62/120 reads (52%) | called by mutect2, pindel, varscan2
- ADCY3 | c.789G>A p.E263= | Silent (SNP) | VAF 112/275 reads (41%) | catalogued as COSV53166255, COSV99568210; called by muse, mutect2, varscan2
- ADGRB3 | c.3375C>T p.S1125= | Silent (SNP) | VAF 145/353 reads (41%) | catalogued as COSV53240324; called by muse, mutect2, varscan2
- ANKRD1 | c.648T>C p.D216= | Silent (SNP) | VAF 36/97 reads (37%) | catalogued as COSV65467399; called by muse, mutect2, varscan2
- ARHGEF9 | c.498G>T p.L166= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as COSV53636864; called by muse, mutect2, varscan2
- ATP10B | c.3771G>A p.V1257= | Silent (SNP) | VAF 48/83 reads (58%) | catalogued as COSV59148124; called by muse, mutect2, varscan2
- ATP6V1C1 | c.141G>T p.T47= | Silent (SNP) | VAF 55/210 reads (26%) | catalogued as rs1424437697, COSV67777777; called by muse, mutect2, varscan2
- CABIN1 | c.6264G>A p.E2088= | Silent (SNP) | VAF 20/148 reads (14%) | catalogued as COSV54080306; called by muse, varscan2
- CD163 | c.3063G>A p.K1021= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV63131278; called by muse, mutect2, varscan2
- CMTM2 | c.456C>T p.N152= | Silent (SNP) | VAF 53/135 reads (39%) | catalogued as rs1044981725, COSV51748336; called by muse, mutect2, varscan2
- COL4A6 | c.1674A>G p.G558= | Silent (SNP) | VAF 85/283 reads (30%) | catalogued as COSV57863321; called by muse, mutect2, varscan2
- CREB5 | c.1302G>A p.L434= (on ENST00000357727 / NM_182898.4; = p.L427= on NM_004904.3) | Silent (SNP) | VAF 28/127 reads (22%) | catalogued as COSV63219212; called by muse, mutect2, varscan2
- CYP2E1 | c.390G>T p.L130= | Silent (SNP) | VAF 70/161 reads (43%) | catalogued as COSV53313000; called by muse, mutect2, varscan2
- DDX60 | c.2433C>T p.V811= | Silent (SNP) | VAF 16/186 reads (9%) | catalogued as rs138638907; called by muse, mutect2
- DHX35 | c.495G>T p.P165= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as COSV52669275; called by muse, mutect2, varscan2
- DNAH2 | c.3142C>T p.L1048= | Silent (SNP) | VAF 39/105 reads (37%) | catalogued as rs761722580, COSV66718429; called by muse, mutect2, varscan2
- DPP6 | c.1443C>T p.T481= (on ENST00000377770 / NM_001364500.2; = p.T419= on NM_001936.5) | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as rs755015968, COSV59606169; called by muse, mutect2, varscan2
- DYNLT3 | c.306C>A p.T102= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV66078835; called by muse, mutect2, varscan2
- EIF3K | c.225C>T p.T75= | Silent (SNP) | VAF 60/127 reads (47%) | catalogued as COSV50263937; called by muse, mutect2, varscan2
- EPB41L2 | c.1128A>T p.A376= | Silent (SNP) | VAF 178/260 reads (68%) | catalogued as COSV61354401; called by muse, mutect2, varscan2
- FCRL4 | c.1128T>G p.T376= | Silent (SNP) | VAF 105/273 reads (38%) | catalogued as COSV54861385; called by muse, mutect2, varscan2
- GPR158 | c.1863C>A p.L621= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as COSV66268032; called by muse, mutect2, varscan2
- HDC | c.354C>T p.N118= | Silent (SNP) | VAF 45/132 reads (34%) | catalogued as rs1237992967, COSV51069195; called by muse, mutect2, varscan2
- IL36G | c.270G>A p.K90= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as COSV52078090; called by muse, mutect2, varscan2
- ISM2 | c.669G>A p.S223= | Silent (SNP) | VAF 56/227 reads (25%) | catalogued as rs780304267, COSV53634542; called by muse, mutect2, varscan2
- KRTAP13-4 | c.315G>T p.L105= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as COSV61878999; called by muse, mutect2, varscan2
- KRTAP5-7 | c.114C>A p.P38= | Silent (SNP) | VAF 78/233 reads (33%) | catalogued as COSV68325171, COSV68325704; called by muse, varscan2
- LRP1 | c.4887G>A p.V1629= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV54507386; called by muse, mutect2, varscan2
- LYZL1 | c.327G>C p.T109= (on ENST00000375500; = p.T63= on NM_032517.6) | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV64966225; called by muse, mutect2, varscan2
- MRGPRE | c.291C>G p.T97= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV67745646; called by muse, mutect2
- MYO5A | c.378A>T p.A126= | Silent (SNP) | VAF 41/127 reads (32%) | catalogued as COSV62558825; called by muse, mutect2, varscan2
- NLRP1 | c.3423A>G p.P1141= | Silent (SNP) | VAF 40/129 reads (31%) | catalogued as rs769035224, COSV52563410; called by muse, mutect2, varscan2
- OPN5 | c.219C>T p.I73= | Silent (SNP) | VAF 16/184 reads (9%) | catalogued as COSV55244775, COSV55244988, COSV55246285; called by muse, mutect2
- OR13G1 | c.87C>A p.L29= | Silent (SNP) | VAF 69/91 reads (76%) | catalogued as COSV62943849; called by muse, mutect2, varscan2
- OR2A25 | c.417C>T p.V139= | Silent (SNP) | VAF 70/199 reads (35%) | catalogued as COSV68717064; called by muse, varscan2
- PCDH17 | c.2184C>G p.V728= | Silent (SNP) | VAF 46/72 reads (64%) | catalogued as COSV64973231; called by muse, mutect2, varscan2
- PCNX1 | c.1581C>T p.S527= | Silent (SNP) | VAF 9/173 reads (5%) | catalogued as COSV53092510; called by muse, mutect2
- PDE4D | c.132C>T p.R44= | Silent (SNP) | VAF 95/135 reads (70%) | catalogued as COSV72351546; called by muse, mutect2, varscan2
- PPP3R2 | c.375G>C p.T125= | Silent (SNP) | VAF 80/123 reads (65%) | catalogued as COSV62452382, COSV62454304; called by muse, mutect2, varscan2
- SHROOM2 | c.2250C>A p.G750= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV66605655; called by muse, mutect2, varscan2
- SLC1A6 | c.1689T>A p.A563= | Silent (SNP) | VAF 22/31 reads (71%) | catalogued as COSV55669506; called by muse, varscan2
- SOX6 | c.2244T>G p.T748= (on ENST00000528429 / NM_001145819.2; = p.T721= on NM_017508.3) | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV57042403; called by muse, mutect2, varscan2
- TENM1 | c.861G>T p.V287= | Silent (SNP) | VAF 71/242 reads (29%) | catalogued as COSV64429329; called by muse, mutect2, varscan2
- TLR4 | c.1407C>A p.G469= (on ENST00000355622 / NM_138554.5; = p.G429= on NM_003266.4) | Silent (SNP) | VAF 67/215 reads (31%) | catalogued as COSV62922862; called by muse, mutect2, varscan2
- TMEM196 | c.321C>A p.S107= | Silent (SNP) | VAF 40/74 reads (54%) | catalogued as COSV68254599; called by muse, mutect2, varscan2
- TRPM1 | c.2448C>A p.I816= | Silent (SNP) | VAF 48/121 reads (40%) | catalogued as rs376705938, COSV56633135; called by muse, mutect2, varscan2
- XPR1 | c.1527G>T p.V509= | Silent (SNP) | VAF 135/408 reads (33%) | catalogued as COSV62555695; called by muse, mutect2, varscan2
- ZC3H12B | c.2439G>A p.E813= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV59047201; called by muse, mutect2, varscan2
- ZDHHC15 | c.63C>A p.S21= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as COSV64901233; called by muse, mutect2, varscan2
- ERCC6 | c.1397+6967G>T | Intron (SNP) | VAF 73/220 reads (33%) | catalogued as COSV63389037; called by muse, mutect2, varscan2
- HMGN2P46 | n.1163G>C | RNA (SNP) | VAF 28/93 reads (30%) | called by muse, mutect2, varscan2
- TTN | c.10361-5269A>G | Intron (SNP) | VAF 61/220 reads (28%) | catalogued as rs578160962, COSV59981840; called by muse, mutect2, varscan2
